Somatic mutation profile of tumor specimen TARGET-30-PAUFUS-01A (aliquot TARGET-30-PAUFUS-01A-01D) from TARGET case TARGET-30-PAUFUS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.4 years (864 days).
Specimen TARGET-30-PAUFUS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a895a37-f88f-4ce4-aee1-59cb71f17396.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUFUS-10A (Blood Derived Normal), aliquot TARGET-30-PAUFUS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83bc16a4-d418-4821-9162-9d0accff8b39

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3520T>G p.F1174V | Missense Mutation (SNP) | VAF 48/221 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs281864719, CM113795, COSV66556166, COSV66559314, COSV66568713; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DOCK8 | c.2157G>A p.K719= | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as COSV66623112; called by muse, mutect2, varscan2
